Somatic mutation profile of tumor specimen TCGA-DD-AAD0-01A (aliquot TCGA-DD-AAD0-01A-11D-A40R-10) from TCGA case TCGA-DD-AAD0, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 73.3 years (26,781 days).
Specimen TCGA-DD-AAD0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 320106c3-02ce-45a9-a8f7-2db9a602dc8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAD0-10A (Blood Derived Normal), aliquot TCGA-DD-AAD0-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c64e3797-aa4f-4532-a0bf-6934a8c9c29e

The open-access MAF lists 116 somatic variants for this specimen: 88 protein-altering or splice-affecting, 24 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 24, Nonsense Mutation 11, Frame Shift Del 4, Intron 2, Splice Site 2, 3'Flank 1, Translation Start Site 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 54/115 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.4549C>T p.R1517* | Nonsense Mutation (SNP) | VAF 26/60 reads (43%) | catalogued as rs1459799356, COSV55860009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 61/143 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.2098C>A p.P700T (on ENST00000272895 / NM_173076.3; = p.P382T on NM_015657.3) | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV55964880, COSV99792553; called by muse, mutect2, varscan2
- ANK1 | c.1043G>A p.C348Y | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV99227261; called by muse, mutect2, varscan2
- APBA1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.017); catalogued as COSV99597374; called by muse, mutect2, varscan2
- ARHGAP39 | c.1552G>C p.V518L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99432458; called by muse, mutect2, varscan2
- ARMCX6 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100726261; called by muse, mutect2, varscan2
- ARRDC5 | c.416T>C p.M139T (on ENST00000381781; = p.M125T on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV101108302; called by muse, mutect2, varscan2
- ATP8B2 | c.2901G>A p.M967I (on ENST00000672630; = p.M934I on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.085); catalogued as rs1248313118, COSV100528313; called by muse, mutect2, varscan2
- BAZ2B | c.2898+1G>T p.X966_splice | Splice Site (SNP) | VAF 126/262 reads (48%) | catalogued as rs1407995331, COSV99681094; called by muse, mutect2, varscan2
- BHLHE40 | c.256A>C p.T86P | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99848335; called by muse, mutect2, varscan2
- CAMK1G | c.945C>A p.H315Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99152356; called by muse, mutect2, varscan2
- CARMIL3 | c.2198C>G p.P733R | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100549948; called by muse, mutect2, varscan2
- CCDC183 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV100566093; called by muse, mutect2, varscan2
- CCT7 | c.1435A>T p.I479F | Missense Mutation (SNP) | VAF 87/219 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.93); catalogued as COSV54582978, COSV99241298; called by muse, mutect2, varscan2
- CHIC1 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV100998251; called by muse, varscan2
- CLDN8 | c.403A>C p.I135L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99730031; called by muse, mutect2, varscan2
- CNOT1 | c.4068G>T p.Q1356H | Missense Mutation (SNP) | VAF 96/171 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV99801559; called by muse, mutect2, varscan2
- COL4A5 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 225/524 reads (43%) | catalogued as COSV100090506; called by muse, mutect2, varscan2
- COPA | c.212A>G p.D71G | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99617067; called by muse, mutect2
- CR1 | c.5101C>T p.P1701S | Missense Mutation (SNP) | VAF 115/176 reads (65%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV100888102; called by muse, mutect2, varscan2
- CTNNA2 | c.2122G>T p.G708C | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100559937, COSV58167219, COSV99057391; called by muse, mutect2, varscan2
- CTNNA2 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100562338; called by muse, mutect2, varscan2
- CYP21A2 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 241/576 reads (42%) | catalogued as COSV100926763, COSV64474914; called by muse, mutect2, varscan2
- DCN | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 40/112 reads (36%) | catalogued as COSV50007217; called by muse, mutect2, varscan2
- DGAT2L6 | c.671C>A p.S224Y | Missense Mutation (SNP) | VAF 114/230 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100284184; called by muse, mutect2, varscan2
- DLG2 | c.214G>C p.E72Q (on ENST00000650630 / NM_001351274.2; = p.E35Q on NM_001142699.3) | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV101075824; called by muse, mutect2, varscan2
- EIF5AL1 | c.380A>C p.Y127S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV101592836, COSV73122947; called by muse, mutect2, varscan2
- ERMARD | c.2020A>G p.S674G | Missense Mutation (SNP) | VAF 83/88 reads (94%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100824639; called by muse, mutect2, varscan2
- FBXO28 | c.608T>G p.I203R | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100837505; called by muse, mutect2, varscan2
- FCN1 | c.593C>G p.A198G | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV100878996; called by muse, mutect2, varscan2
- GAL3ST3 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV100361028; called by muse, mutect2, varscan2
- GREB1 | c.2924C>T p.A975V | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as rs778741413, COSV99304023; called by muse, mutect2, varscan2
- HEATR9 | c.290A>T p.K97M | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1376221810; called by muse, mutect2, varscan2
- KCNMB3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 37/89 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100046718; called by muse, mutect2, varscan2
- KMT2B | c.2672C>G p.P891R | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99720856; called by muse, mutect2, varscan2
- KRTAP1-3 | c.55A>G p.T19A | Missense Mutation (SNP) | VAF 98/134 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV60336062; called by muse, mutect2, varscan2
- MBOAT2 | c.644A>T p.N215I | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100020737; called by muse, mutect2
- MBOAT2 | c.642A>C p.E214D | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs748274292, COSV100020738; called by muse, mutect2
- MS4A6E | c.418G>C p.V140L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); catalogued as COSV100279256; called by muse, mutect2, varscan2
- MYH6 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1425571023, COSV62448325; called by muse, mutect2, varscan2
- NIPBL | c.771C>T p.D257= | Splice Region (SNP) | VAF 80/188 reads (43%) | catalogued as rs771594948, COSV56966360; called by muse, mutect2, varscan2
- NSUN6 | c.1066A>T p.T356S | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV101046058; called by muse, mutect2, varscan2
- NTRK3 | c.1864C>A p.H622N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.893); catalogued as COSV100714159, COSV62299502; called by muse, mutect2, varscan2
- OR5D14 | c.200A>C p.H67P | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV100162672, COSV59456041; called by muse, mutect2, varscan2
- OTOGL | c.5270C>A p.S1757* (on ENST00000547103; = p.S1748* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 48/81 reads (59%) | catalogued as COSV100088064; called by muse, mutect2, varscan2
- PARVA | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 44/112 reads (39%) | catalogued as rs758509655, COSV100616908; called by muse, mutect2, varscan2
- PCDH10 | c.1211G>T p.R404L | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV99992585, COSV99994753; called by muse, mutect2, varscan2
- PHF11 | c.364T>A p.C122S | Missense Mutation (SNP) | VAF 125/289 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100710674; called by muse, mutect2, varscan2
- PHYHIPL | c.1028G>C p.G343A | Missense Mutation (SNP) | VAF 44/46 reads (96%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99514805; called by muse, mutect2
- PLEKHH1 | c.2107A>C p.K703Q | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100233555; called by muse, mutect2, varscan2
- PLXNB2 | c.3719G>T p.G1240V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV100834363; called by muse, mutect2, varscan2
- PSMB11 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99944375; called by muse, mutect2, varscan2
- PTEN | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 118/137 reads (86%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as CM132269, COSV100911310, COSV64292596, COSV64307072; called by muse, mutect2
- RAB39B | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV101035062; called by muse, mutect2, varscan2
- RCN2 | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 124/260 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100312904; called by muse, mutect2, varscan2
- RHOU | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV100797219; called by muse, mutect2, varscan2
- RP1 | c.2663C>G p.A888G | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as COSV99609178; called by muse, mutect2, varscan2
- SCG2 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100544966; called by muse, mutect2, varscan2
- SCUBE3 | c.933C>G p.I311M | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV99235400; called by muse, mutect2, varscan2
- SETD2 | c.4454+2T>G p.X1485_splice | Splice Site (SNP) | VAF 25/43 reads (58%) | catalogued as COSV100339692; called by muse, mutect2, varscan2
- SFXN5 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 91/201 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as COSV99730145; called by muse, mutect2, varscan2
- SGSM1 | c.553A>G p.M185V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as COSV101241240; called by muse, mutect2, varscan2
- SHH | c.1302G>A p.W434* | Nonsense Mutation (SNP) | VAF 343/705 reads (49%) | catalogued as COSV99793629; called by muse, mutect2, varscan2
- SLC23A1 | c.1285G>C p.G429R | Missense Mutation (SNP) | VAF 110/263 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100812130; called by muse, mutect2, varscan2
- SLC9C1 | c.2617G>T p.D873Y | Missense Mutation (SNP) | VAF 135/304 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99998983; called by muse, mutect2, varscan2
- SMC1A | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100447729; called by muse, mutect2, varscan2
- SP110 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs745817983, COSV51247407, COSV51266921; called by muse, mutect2
- SPTBN2 | c.6049G>T p.V2017L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100020732; called by muse, mutect2, varscan2
- SSX7 | c.93C>A p.Y31* | Nonsense Mutation (SNP) | VAF 321/699 reads (46%) | catalogued as COSV53341045; called by muse, mutect2, varscan2
- SYNDIG1L | c.88C>G p.P30A | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100526617; called by muse, mutect2, varscan2
- TADA2B | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 53/120 reads (44%) | catalogued as COSV53827509, COSV99380808; called by muse, mutect2, varscan2
- TAF10 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100196690; called by muse, mutect2, varscan2
- TAT | c.779A>G p.Y260C | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100587747; called by muse, mutect2, varscan2
- TATDN2 | c.452C>G p.S151C | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV99813815; called by muse, mutect2, varscan2
- TENM1 | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV100951242; called by muse, mutect2, varscan2
- THADA | c.5311C>A p.Q1771K | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT tolerated (0.94); PolyPhen benign (0.071); catalogued as COSV100369682; called by muse, mutect2, varscan2
- TIMM10B | c.107T>C p.L36S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99601720; called by muse, mutect2, varscan2
- TMEM87B | c.753G>A p.W251* | Nonsense Mutation (SNP) | VAF 47/92 reads (51%) | catalogued as COSV99314761; called by muse, mutect2, varscan2
- ZBTB32 | c.1435C>A p.P479T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV99386319; called by muse, mutect2, varscan2
- ZC3H6 | c.3248G>T p.S1083I | Missense Mutation (SNP) | VAF 143/290 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as COSV100674864; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 129/281 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.291); catalogued as COSV100606366; called by muse, mutect2, varscan2
- ZNF93 | c.826A>T p.K276* | Nonsense Mutation (SNP) | VAF 40/74 reads (54%) | catalogued as COSV100652461; called by muse, mutect2, varscan2
- MYO9B | c.2602del p.L868Wfs*57 | Frame Shift Del (DEL) | VAF 30/60 reads (50%) | called by mutect2, pindel, varscan2
- RCOR3 | c.943_947del p.V315Wfs*20 | Frame Shift Del (DEL) | VAF 71/241 reads (29%) | called by mutect2, pindel, varscan2
- ZBTB9 | c.681del p.S228Qfs*28 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | called by mutect2, pindel, varscan2
- ZNF506 | c.1152_1179del p.T385Rfs*33 | Frame Shift Del (DEL) | VAF 28/67 reads (42%) | called by mutect2, pindel, varscan2
- ADGRF2 | c.561A>G p.L187= (on ENST00000296862 / NM_001368115.2; = p.L119= on NM_153839.7) | Silent (SNP) | VAF 90/205 reads (44%) | catalogued as COSV99732002; called by muse, mutect2, varscan2
- AMIGO3 | c.1467C>A p.G489= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100246555; called by mutect2, varscan2
- BICRA | c.3924C>T p.L1308= | Silent (SNP) | VAF 78/154 reads (51%) | catalogued as rs1212491235, COSV101194507; called by muse, mutect2, varscan2
- C1orf112 | c.1359C>A p.T453= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV99610290; called by muse, mutect2, varscan2
- CACNA1C | c.1185C>T p.F395= | Silent (SNP) | VAF 53/135 reads (39%) | catalogued as rs1455190942, COSV59713206; called by muse, mutect2, varscan2
- FREM2 | c.7563G>C p.P2521= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV54846562, COSV99751489; called by muse, mutect2, varscan2
- GSDME | c.312G>A p.G104= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as rs1313102640, COSV100742474; called by muse, mutect2, varscan2
- GUCY2F | c.228G>A p.A76= | Silent (SNP) | VAF 171/372 reads (46%) | catalogued as rs755144575, COSV99485862; called by muse, mutect2, varscan2
- ICE1 | c.1935C>T p.P645= | Silent (SNP) | VAF 50/104 reads (48%) | catalogued as COSV99666011; called by muse, mutect2, varscan2
- ITGAD | c.1563G>A p.G521= | Silent (SNP) | VAF 55/108 reads (51%) | catalogued as COSV101210505, COSV101210628; called by muse, mutect2, varscan2
- MPP3 | c.798C>T p.D266= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as rs377033537, COSV68199332; called by muse, mutect2, varscan2
- NDN | c.276G>T p.P92= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100086784, COSV100086808; called by muse, mutect2, varscan2
- PRSS1 | c.576C>A p.G192= | Silent (SNP) | VAF 71/174 reads (41%) | catalogued as COSV100298555; called by muse, mutect2, varscan2
- RARS1 | c.249C>G p.V83= | Silent (SNP) | VAF 56/101 reads (55%) | catalogued as COSV99199255; called by muse, mutect2, varscan2
- SYNE2 | c.17589G>A p.Q5863= | Silent (SNP) | VAF 64/152 reads (42%) | catalogued as COSV100648620; called by muse, mutect2, varscan2
- TBC1D16 | c.1605C>T p.D535= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as rs756414717, COSV100188468; called by muse, mutect2, varscan2
- TM4SF4 | c.378A>G p.T126= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as rs571739504, COSV59516621; called by muse, mutect2, varscan2
- TRIM36 | c.1281C>T p.S427= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV99142883; called by muse, mutect2, varscan2
- TTC29 | c.1110C>T p.Y370= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs1329567183, COSV100283769, COSV100284766; called by muse, mutect2, varscan2
- USF1 | c.225T>G p.T75= | Silent (SNP) | VAF 53/158 reads (34%) | catalogued as COSV99231354; called by muse, mutect2, varscan2
- ZNF124 | c.777A>G p.E259= (on ENST00000543802 / NM_001297568.1; = p.E197= on NM_003431.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/137 reads (27%) | catalogued as COSV100517941; called by muse, mutect2, varscan2
- ZNF516 | c.1029G>T p.L343= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV101487387; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.264G>A p.G88= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100008512; called by muse, mutect2, varscan2
- ZNF835 | c.1566T>C p.C522= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV101606419; called by muse, mutect2, varscan2
- MYL3 | chr3:46830493 C>T | 3'Flank (SNP) | VAF 28/60 reads (47%) | catalogued as COSV70134143; called by muse, mutect2, varscan2
- NOS1AP | c.454-1273A>T | Intron (SNP) | VAF 66/210 reads (31%) | catalogued as COSV100723678; called by muse, mutect2, varscan2
- OBSCN | c.18662-2126G>T | Intron (SNP) | VAF 19/60 reads (32%) | catalogued as COSV99485813; called by muse, mutect2, varscan2
- SSPOP | n.3387G>A | RNA (SNP) | VAF 12/30 reads (40%) | catalogued as COSV50486882; called by muse, mutect2, varscan2
